Somatic mutation profile of tumor specimen TCGA-TQ-A7RQ-01A (aliquot TCGA-TQ-A7RQ-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RQ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.8 years (14,187 days).
Specimen TCGA-TQ-A7RQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77233dbd-84f3-4c06-8b88-8d8563dfb708.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RQ-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RQ-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/796ddb5e-1830-4efb-b4aa-5b232474558c

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 2, In Frame Del 1, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/164 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACP1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs375641056; called by muse, mutect2, varscan2
- ASB9 | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995380; called by muse, mutect2
- BCOR | c.3789G>T p.E1263D (on ENST00000378444 / NM_001123385.2; = p.E1229D on NM_017745.6) | Missense Mutation (SNP) | VAF 151/361 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV60721479; called by muse, mutect2, varscan2
- CAB39 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1196616191, COSV51477549; called by muse, mutect2, varscan2
- ELMO3 | c.1052G>A p.R351Q (on ENST00000652269; = p.R298Q on NM_024712.5) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs777708052, COSV100681496, COSV62606638; called by muse, mutect2, varscan2
- GFOD1 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs868423927, COSV101014949; called by muse, mutect2
- GPR101 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV53239789, COSV53240383; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1009A>C p.N337H | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.687); catalogued as COSV100780748; called by muse, mutect2
- ITIH6 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99512874, COSV99513956; called by muse, mutect2, varscan2
- ITPK1 | c.121-2A>G p.X41_splice | Splice Site (SNP) | VAF 28/92 reads (30%) | catalogued as COSV50898321, COSV99968251; called by muse, mutect2, varscan2
- MIER2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); catalogued as COSV99316042; called by muse, mutect2
- MYO1F | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100596392; called by muse, mutect2, varscan2
- RNF135 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100103959; called by muse, mutect2
- RNPEP | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99821240; called by muse, mutect2
- RYR3 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.174); catalogued as rs752846417, COSV66779860; ClinVar: uncertain significance; called by muse, mutect2
- SEC22C | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771129762, COSV99827336; called by muse, mutect2, varscan2
- CIC | c.2507_2531del p.L836Qfs*80 | Frame Shift Del (DEL) | VAF 19/29 reads (66%) | called by mutect2, pindel, varscan2
- GPR37L1 | c.838_846del p.M280_T282del | In Frame Del (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- TMEM236 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 248/574 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF292 | c.5557del p.L1853Yfs*10 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | called by mutect2, pindel, varscan2
- CDX4 | c.90C>T p.G30= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100999107, COSV100999139; called by muse, mutect2, varscan2
- EIF2AK4 | c.924C>T p.V308= | Silent (SNP) | VAF 106/224 reads (47%) | catalogued as COSV99774109; called by muse, mutect2, varscan2
- EMD | c.156C>T p.S52= | Silent (SNP) | VAF 69/158 reads (44%) | catalogued as COSV63962119; called by muse, mutect2, varscan2
- FLNC | c.1314C>T p.C438= | Silent (SNP) | VAF 10/270 reads (4%) | catalogued as COSV100367660; called by muse, mutect2
- LRBA | c.2274C>T p.V758= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV100840978; called by muse, mutect2, varscan2
- TECTB | c.732C>T p.F244= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV101027638; called by muse, mutect2, varscan2
- ZNF254 | c.1929G>A p.S643= | Silent (SNP) | VAF 22/296 reads (7%) | catalogued as rs770494112, COSV61641806; called by muse, mutect2
- ARHGAP39 | c.2522-3569A>G | Intron (SNP) | VAF 75/285 reads (26%) | catalogued as COSV99430309; called by muse, mutect2, varscan2
